Somatic mutation profile of tumor specimen TARGET-10-PARPPV-09A (aliquot TARGET-10-PARPPV-09A-01D) from TARGET case TARGET-10-PARPPV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.1 years (5,143 days).
Specimen TARGET-10-PARPPV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e474195-1831-4b48-96ed-7a97271141b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPPV-10A (Blood Derived Normal), aliquot TARGET-10-PARPPV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0850c7e8-3fce-489a-9701-ae617d561cee

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 20/20 reads (100%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MUC16 | c.36115C>T p.R12039W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs369910554; called by muse, mutect2, varscan2
- NAA15 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs767646448; called by muse, mutect2, varscan2
- SLITRK6 | c.56A>C p.H19P | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- USP9Y | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- XPO5 | c.2338A>C p.I780L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARHGAP39 | c.738C>T p.S246= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs370518375; called by muse, mutect2, varscan2
- CACNG6 | c.*74G>A | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- DRC7 | c.1759-62C>T | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1000+37G>C | Intron (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- TMEM132D | c.968+34C>T | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
